Surgical pathology report (de-identified scan), TCGA case TCGA-55-8508, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8508-01A (Primary Tumor).

Final Diagnosis

Interlobar lymph node:

One lymph node negative for malignancy.

Right upper lobe of lung, lobectomy:

Pulmonary adenocarcinoma with diffuse mucin production.

Tumor measures 3.7 cm in maximum gross dimension.

Tumor does not involve overlying pleural surface.

Small peripheral nodular area of pulmonary adenocarcinoma located 1.2 cm from main mass (0.8 cm in maximum dimension) similar in histology to primary adenocarcinoma.

Bronchial margin surgical resection free.

Peribronchial lymph nodes: One of five lymph nodes positive for metastatic adenocarcinoma.

Pathological AJCC stage: T2a,N1.

Clinical Information

Lung mass.

Gross Description

"A, Interlobar node." The specimen consists of a 0.7 x 0.6 x 0.4 cm anthracotic lymph node.

"B, Upper lobe lung." The specimen consists of a 14.7 x 11.7 x 2.5 cm portion of lung. The pleural surface is red-gray with mild adhesions. There is a 3.6 cm firm elevated puckered area present on the pleural surface. This area has previously been inked black by the pathologist. The specimen has previously been partially sectioned and there is a 3.7 x 3.3 x 1.5 cm ill-defined firm gray-tan mass which abuts the overlying pleural surface and comes to within 3 cm of the bronchial margin. On further examination there is a 0.8 x 0.7 x 0.7 cm ill-defined firm gray-tan mass which lies 1.2 cm from the larger mass. This mass comes to within 1 cm of the overlying pleural surface and lies 4.3 cm from the bronchial margin. The remaining lung parenchyma is red-tan and mildly congested and no additional lesions or areas of interest are grossly identified. Mild emphysematous change is noted at the periphery of the specimen. Five possible peribronchial lymph nodes are identified. These range in size from 0.6 to 0.9 cm. "B1," bronchial and vascular margins; "B2-B4," mass #1 with overlying pleura; "B5," mass #1 with adjacent parenchyma; "B6," mass #2; "B7," emphysematous change; "B8," peribronchial lymph nodes.

Source: NCI Genomic Data Commons file 34e137e7-6a0d-4a87-a045-940eb0bba2ba (TCGA-55-8508.C5D96896-7988-469A-B521-39AFFEAB8F95.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).